Gene-level copy-number profile of tumor specimen ALCH-AEDY-TTP1-A from ALCHEMIST case ALCH-AEDY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 50.6 years (18,486 days).
Specimen ALCH-AEDY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 728c3a35-b475-4524-b952-420da0d08c42.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEDY-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/fdc4113a-bf1c-4c68-bbb7-fb8efe140885

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 168; copy number 1: 4,284; copy number 2: 54,324; copy number 3: 133; copy number 4: 5.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:33,540,040–33,540,493, 2 genes: SNORA70, RPL10P18.
- chr9:136,483,495–136,486,067, 1 gene (within-gene range 0–1): C9orf163.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,595. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
